Gene-level copy-number profile of tumor specimen TCGA-GD-A76B-01A from TCGA case TCGA-GD-A76B, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 86.4 years (31,571 days).
Specimen TCGA-GD-A76B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.87405517-44ea-43f8-b2cc-8b25f36957f0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GD-A76B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f46e8fe-3606-49f3-b2a4-21d770343376

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,559; copy number 3: 19,383; copy number 4: 15,205; copy number 5: 13,436; copy number 6: 7,232.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GD-A76B-01A-11D-A32A-01): tumor purity 0.48, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
